Somatic mutation profile of tumor specimen TCGA-DU-6403-01A (aliquot TCGA-DU-6403-01A-11D-1705-08) from TCGA case TCGA-DU-6403, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.3 years (22,031 days).
Specimen TCGA-DU-6403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 822e2a4b-d7b5-4896-84a4-d486ec282424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6403-10A (Blood Derived Normal), aliquot TCGA-DU-6403-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b956d7af-f2a0-4c24-a855-1aaf729bac3c

The open-access MAF lists 61 somatic variants for this specimen: 51 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 8, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs202116091; called by muse, mutect2, varscan2
- AFF2 | c.3764G>T p.R1255L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54001843, COSV54003160; called by muse, mutect2, varscan2
- AGBL5 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780394281, COSV59935830; called by muse, mutect2, varscan2
- ASTN1 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs777093050, COSV62504008; called by muse, mutect2, varscan2
- BCOR | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as rs745720817, COSV60699551; called by muse, mutect2, varscan2
- BCOR | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60701324, COSV60715630; called by muse, mutect2, varscan2
- CYBB | c.883G>C p.V295L | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV66086111; called by muse, mutect2, varscan2
- CYP4F3 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs375318772, COSV55409460, COSV55410867; called by muse, mutect2, varscan2
- DLGAP5 | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV55964930; called by muse, mutect2, varscan2
- DNAI3 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV54002296; called by muse, mutect2, varscan2
- DVL2 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as rs764074788, COSV50038853; called by muse, mutect2, varscan2
- ESAM | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs752354928, COSV54036437; called by muse, mutect2, varscan2
- FAM71B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57230359; called by muse, mutect2, varscan2
- FLG | c.7595C>T p.S2532L | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); catalogued as rs756739106, COSV64236669; called by muse, mutect2, varscan2
- GRHL2 | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52553271; called by muse, mutect2, varscan2
- HECW1 | c.4248+1G>C p.X1416_splice | Splice Site (SNP) | VAF 27/170 reads (16%) | catalogued as COSV67838016; called by muse, mutect2, varscan2
- HGF | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as rs1303795573, COSV55946618, COSV55955205; called by muse, mutect2, varscan2
- KRT31 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs371629655; called by muse, mutect2
- L1CAM | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs782367123, COSV62826709, COSV62827874; called by muse, mutect2, varscan2
- LBH | c.27-1G>T p.X9_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | catalogued as COSV68049992; called by muse, mutect2, varscan2
- MPPED1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV68839034; called by muse, mutect2, varscan2
- MYH11 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774279707, COSV55562098; ClinVar: uncertain significance; called by muse, mutect2
- MYOCD | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs372478735, COSV58503063; called by muse, mutect2, varscan2
- NDST3 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs763238949, COSV56627146; called by muse, mutect2, varscan2
- OR2A5 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV68739048; called by muse, mutect2, varscan2
- OR5AP2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756963104, COSV57257858; called by muse, mutect2, varscan2
- OR6K3 | c.763A>C p.T255P (on ENST00000368146; = p.T239P on NM_001005327.2) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269354188, COSV63746310; called by muse, mutect2, varscan2
- PCDH19 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55264694, COSV55269592; called by muse, mutect2, varscan2
- PCDHGB4 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs766365115, COSV53955001; called by muse, mutect2, varscan2
- PDE11A | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV53705527; called by muse, mutect2, varscan2
- PHKA2 | c.3388C>G p.R1130G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV66053063, COSV66055712; called by muse, mutect2, varscan2
- PKHD1 | c.4804A>C p.N1602H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV61890803; called by muse, mutect2, varscan2
- PRCP | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761508715, COSV57291158; called by muse, mutect2, varscan2
- PRSS12 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56609218; called by muse, mutect2, varscan2
- RAPGEF6 | c.4133G>A p.S1378N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV57253926; called by muse, mutect2, varscan2
- RTP5 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as rs202220121, COSV58319499; called by muse, mutect2, varscan2
- SENP5 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV60209463, COSV60209576; called by muse, mutect2, varscan2
- SI | c.4036A>G p.T1346A | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV52295959; called by muse, mutect2
- SLC25A53 | c.755G>T p.W252L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs782246240, COSV62460404; called by muse, mutect2, varscan2
- SLC35F3 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as rs769842963, COSV64031483, COSV64033414; called by muse, mutect2, varscan2
- SNCA | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767026129, COSV61133182; called by muse, mutect2, varscan2
- SPAG17 | c.4169T>G p.I1390R | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV60466093; called by muse, mutect2, varscan2
- TDRD3 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV52162122; called by muse, mutect2
- TFDP3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1239930035, COSV59536633; called by muse, mutect2, varscan2
- TLR6 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs374845111; called by muse, mutect2, varscan2
- TSC1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV53771754; called by muse, mutect2, varscan2
- ADAMTS4 | c.261_262dup p.F88Sfs*8 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- PSME4 | c.3639del p.K1213Nfs*3 | Frame Shift Del (DEL) | VAF 63/237 reads (27%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1070C>G p.S357W | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX33 | c.739del p.D247Ifs*11 (on ENST00000381821 / NM_001163857.2; = p.D162Ifs*11 on NM_178552.4) | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.2); called by muse, varscan2
- AC004593.2 | c.888G>A p.T296= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs759715921, COSV56099744; called by muse, mutect2, varscan2
- ATP8B3 | c.3462C>T p.Y1154= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs757021841, COSV59547321; called by muse, mutect2, varscan2
- DUOX2 | c.1263C>T p.S421= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV66532067; called by muse, mutect2, varscan2
- GALNT17 | c.63C>T p.F21= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV61184720; called by muse, mutect2
- GRIA1 | c.2361C>T p.C787= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs755459632, COSV53598399, COSV53629481; called by muse, mutect2, varscan2
- HRNR | c.1239C>T p.R413= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs752238836, COSV64261879; called by muse, mutect2, varscan2
- PCDHB2 | c.1665C>T p.D555= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1554271519, COSV99165342; called by mutect2, varscan2
- PCLO | c.300G>A p.P100= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs547486813, COSV61659300; called by muse, mutect2, varscan2
- MIR548I2 | n.133G>A | RNA (SNP) | VAF 61/191 reads (32%) | catalogued as rs780852741; called by muse, mutect2, varscan2
- SCRIB | c.643-14C>G | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs1348273917, COSV100253496; called by muse, mutect2
